CCDI case PBBYNW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/43b6402b-5a7e-4102-8ddb-6c12a415f9ea

Demographics
Sex at birth: male; Race: white; Vital status: Dead.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 21.1 years (7,695 days).

Biospecimens (3 samples)
- Sample 0DKWN2: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DKWND: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DKWNP: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
